Somatic mutation profile of tumor specimen TCGA-85-8049-01A (aliquot TCGA-85-8049-01A-11D-2244-08) from TCGA case TCGA-85-8049, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 57.5 years (20,995 days).
Specimen TCGA-85-8049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d396452-a676-4166-9c4d-2711b8d7695e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8049-10A (Blood Derived Normal), aliquot TCGA-85-8049-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e32cc22-5f00-4370-a046-d92a3c880d0f

The open-access MAF lists 240 somatic variants for this specimen: 177 protein-altering or splice-affecting, 54 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 54, Nonsense Mutation 15, Frame Shift Del 6, Splice Site 5, RNA 5, Intron 3, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 25/115 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2
- ABCA10 | c.3851G>T p.G1284V | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288324; called by muse, mutect2
- ABCB6 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV99202394; called by muse, mutect2
- ADAMTS19 | c.3014G>T p.R1005I | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99177105; called by muse, mutect2, varscan2
- AHNAK2 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs565473345, COSV60932935; called by muse, mutect2
- AMN1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99861474; called by muse, mutect2
- APC | c.136-2A>T p.X46_splice | Splice Site (SNP) | VAF 18/248 reads (7%) | catalogued as COSV99966947; called by muse, mutect2
- APOL5 | c.302T>A p.L101* | Nonsense Mutation (SNP) | VAF 43/172 reads (25%) | catalogued as COSV99968357; called by muse, mutect2, varscan2
- AQP12B | c.162C>A p.D54E (on ENST00000621682; = p.D66E on NM_001102467.2) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101315861; called by muse, mutect2, varscan2
- ARGFX | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 24/201 reads (12%) | catalogued as COSV100544102; called by muse, mutect2, varscan2
- ARMC3 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs200309888, COSV99957797; called by muse, mutect2, varscan2
- ASB17 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52409524; called by muse, mutect2
- ASIC5 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV72232691, COSV72233239; called by muse, mutect2
- ATR | c.2210A>C p.H737P | Missense Mutation (SNP) | VAF 37/456 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100637992; called by muse, mutect2
- BCL6B | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99546544; called by muse, mutect2, varscan2
- BOD1L1 | c.6280G>A p.G2094S | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV99238994; called by muse, mutect2
- BSN | c.9106C>G p.P3036A | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99607944; called by muse, mutect2, varscan2
- BVES | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.762); catalogued as COSV100114824; called by muse, mutect2, varscan2
- C1orf87 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV64597405; called by muse, mutect2, varscan2
- C2orf16 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101284381; called by muse, mutect2, varscan2
- CATSPERE | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100835056; called by muse, mutect2
- CCR9 | c.250G>A p.D84N (on ENST00000357632 / NM_031200.3; = p.D72N on NM_006641.4) | Missense Mutation (SNP) | VAF 60/659 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200142278, COSV62939737; called by muse, mutect2
- CDH11 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV99217881, COSV99218614; called by muse, mutect2
- CDH7 | c.662A>C p.E221A | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100541946; called by muse, mutect2, varscan2
- CDK8 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101037098, COSV67422673; called by muse, mutect2, varscan2
- CHRM5 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749924788, COSV101271896; called by muse, mutect2, varscan2
- CLEC14A | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100643527; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 34/156 reads (22%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs140716136, COSV62227065; called by muse, mutect2, varscan2
- CNTNAP5 | c.762C>G p.S254R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as COSV101443316; called by muse, mutect2, varscan2
- COL22A1 | c.1510A>T p.I504F | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100277572; called by muse, mutect2, varscan2
- CR1 | c.5042C>A p.P1681H | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100887515; called by muse, mutect2, varscan2
- CRTC1 | c.961A>T p.R321W | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100119257; called by muse, varscan2
- CSMD3 | c.9930G>T p.Q3310H (on ENST00000297405 / NM_001363185.1; = p.Q3141H on NM_052900.3) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV99830650; called by muse, mutect2
- CYP7A1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV100052291; called by muse, mutect2
- DAPK1 | c.552C>A p.V184= | Splice Region (SNP) | VAF 35/274 reads (13%) | catalogued as COSV100801537, COSV100802663; called by muse, mutect2, varscan2
- DCAF4L2 | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV60478085; called by muse, mutect2
- DENND3 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV99370721; called by muse, mutect2, varscan2
- DLC1 | c.3292G>A p.A1098T (on ENST00000276297 / NM_001348081.2; = p.A661T on NM_006094.5) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs750331639, COSV99362345; called by muse, mutect2, varscan2
- DMD | c.9003G>T p.Q3001H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100626708, COSV58898723; called by muse, mutect2, varscan2
- DNAH2 | c.9797G>A p.R3266H | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs931986589, COSV101209158; called by muse, mutect2, varscan2
- DNAH9 | c.7336C>A p.P2446T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99305182; called by muse, mutect2, varscan2
- DNAJC13 | c.6230C>G p.S2077C | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV99607032; called by muse, mutect2
- DYRK2 | c.977G>T p.R326L (on ENST00000344096 / NM_006482.3; = p.R253L on NM_003583.4) | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770414447, COSV100165248; called by muse, mutect2, varscan2
- EPHA5 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56643710, COSV99897943; called by muse, mutect2, varscan2
- EPHB4 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 74/451 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.084); catalogued as rs1181122990, COSV100639464; called by muse, mutect2, varscan2
- FAM114A1 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100729249; called by muse, mutect2, varscan2
- FAM135B | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 41/240 reads (17%) | catalogued as COSV52716547, COSV99421942; called by muse, mutect2, varscan2
- FMR1 | c.990+1G>T p.X330_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99503160; called by muse, mutect2
- GATA1 | c.388A>T p.T130S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100936759; called by muse, mutect2, varscan2
- GATM | c.887T>G p.F296C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV101188188; called by muse, mutect2, varscan2
- GJD2 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99290663; called by muse, mutect2, varscan2
- GLI4 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100390982; called by muse, mutect2, varscan2
- GPATCH2L | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99833501; called by muse, mutect2
- GTPBP3 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1414285372, COSV99344300; called by muse, mutect2, varscan2
- H2AC16 | c.203del p.G68Afs*34 | Frame Shift Del (DEL) | VAF 47/266 reads (18%) | catalogued as COSV58900792; called by mutect2, pindel*, varscan2
- HIP1 | c.2094G>T p.L698F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100417300; called by muse, mutect2, varscan2
- HTR3C | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.284); catalogued as COSV100570547; called by muse, mutect2, varscan2
- HTR3C | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); catalogued as COSV100570468; called by muse, mutect2, varscan2
- HUWE1 | c.3994A>T p.R1332W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99471549; called by mutect2, varscan2
- ICA1 | c.685C>A p.H229N | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV99655140; called by muse, mutect2, varscan2
- IGF2BP3 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV99325238; called by muse, mutect2, varscan2
- IGHG3 | c.1325T>C p.I442T | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs201749189; called by muse, mutect2
- IGHV1-2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 51/484 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); catalogued as rs569214877; called by muse, mutect2, varscan2
- IGHV4-31 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs1176563717; called by muse, mutect2
- IGSF9B | c.518G>T p.W173L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100317349; called by muse, mutect2, varscan2
- IL17RE | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV99924862; called by muse, mutect2, varscan2
- INAVA | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as COSV100949946; called by muse, mutect2, varscan2
- INSL4 | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV99497106; called by muse, mutect2, varscan2
- IPO8 | c.461A>C p.Y154S | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99805070; called by muse, mutect2, varscan2
- ITIH5 | c.1917G>T p.M639I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99904297; called by muse, mutect2
- IZUMO2 | c.396C>A p.A132= | Splice Region (SNP) | VAF 3/30 reads (10%) | catalogued as COSV53231501; called by muse, mutect2
- KCNJ3 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV99715547; called by muse, mutect2, varscan2
- KDR | c.1771C>A p.L591M | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV99817255; called by muse, mutect2
- KLK11 | c.197C>T p.P66L (on ENST00000594768 / NM_144947.3; = p.P34L on NM_006853.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99141872; called by muse, mutect2, varscan2
- LAMC3 | c.4322C>T p.S1441F | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV62654303; called by muse, mutect2
- LRRIQ1 | c.5017-2A>G p.X1673_splice | Splice Site (SNP) | VAF 28/183 reads (15%) | catalogued as COSV101279953; called by muse, mutect2, varscan2
- LRRN1 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100076193, COSV60016179; called by muse, mutect2
- MEIS1 | c.874T>C p.F292L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99714926; called by muse, mutect2
- MLKL | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100087278; called by muse, mutect2
- MMP16 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99687208; called by muse, mutect2, varscan2
- MMP16 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as COSV54149653; called by muse, mutect2, varscan2
- MORC1 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV51717426, COSV51725283; called by muse, mutect2
- MRFAP1L1 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV100299041; called by muse, mutect2, varscan2
- MS4A6A | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs1304345958, COSV100124722; called by muse, mutect2
- MSANTD4 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV100108565; called by muse, mutect2, varscan2
- MUC16 | c.12843G>A p.M4281I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV101199319; called by muse, mutect2, varscan2
- MYO1G | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209756872; called by muse, mutect2
- MYO7B | c.3735C>G p.Y1245* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101268042, COSV67345605; called by mutect2, varscan2
- MYOCD | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590552; called by muse, mutect2, varscan2
- NDST4 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV52120370, COSV99996083; called by muse, mutect2, varscan2
- NLRP12 | c.1782G>A p.W594* | Nonsense Mutation (SNP) | VAF 49/248 reads (20%) | catalogued as rs953567955, COSV100145096; called by muse, mutect2, varscan2
- NLRP4 | c.2508C>A p.C836* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as COSV100016029; called by muse, mutect2
- NPR1 | c.2339T>G p.M780R | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1401892412, COSV100902009; called by muse, mutect2, varscan2
- NUP205 | c.1473+1G>A p.X491_splice | Splice Site (SNP) | VAF 9/137 reads (7%) | catalogued as COSV53668487; called by muse, mutect2
- OLFM3 | c.1237G>A p.G413R (on ENST00000338858 / NM_001288821.1; = p.G393R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129196; called by muse, mutect2, varscan2
- OR2D2 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100203782; called by muse, mutect2, varscan2
- OR2L13 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813717; called by muse, mutect2
- OR4D5 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100189853; called by muse, mutect2
- OR51F2 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100437983, COSV59063842; called by muse, mutect2
- OR5T2 | c.755T>A p.I252N | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV100506889; called by muse, mutect2
- OR8D4 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.182); catalogued as rs1378722164, COSV58432093; called by muse, mutect2, varscan2
- OR8H2 | c.108C>A p.Y36* | Nonsense Mutation (SNP) | VAF 69/750 reads (9%) | catalogued as rs1158520695, COSV100542126, COSV100542243; called by muse, mutect2
- PCDHA11 | c.1703A>T p.Q568L | Missense Mutation (SNP) | VAF 32/419 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100249413; called by muse, mutect2
- PCDHB6 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99170031; called by muse, mutect2, varscan2
- PCDHGB4 | c.1496T>C p.L499P | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99535134; called by muse, mutect2
- PDZD2 | c.4242C>A p.C1414* | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | catalogued as COSV99224545; called by muse, mutect2, varscan2
- PHAX | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1341320080, COSV99881394; called by muse, mutect2, varscan2
- PLOD1 | c.644-1G>A p.X215_splice | Splice Site (SNP) | VAF 40/208 reads (19%) | catalogued as COSV99538077; called by muse, mutect2, varscan2
- PMS1 | c.1987G>C p.A663P | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); catalogued as COSV100575575; called by muse, mutect2, varscan2
- PNMA2 | c.920T>G p.M307R | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101580611; called by muse, mutect2
- POLE | c.4942G>T p.E1648* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100265975, COSV57690090; called by muse, mutect2, varscan2
- POU2F3 | c.1018A>C p.N340H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV52797262, COSV99500938; called by muse, mutect2, varscan2
- PRDM1 | c.1660A>G p.R554G | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100958684; called by muse, mutect2, varscan2
- PTP4A2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100685651; called by muse, mutect2, varscan2
- PTPRB | c.1900C>A p.Q634K | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.599); catalogued as COSV99716786; called by mutect2, varscan2
- PUM2 | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100163441; called by muse, mutect2
- RNF111 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs1325738378, COSV100788916; called by muse, mutect2
- RP1 | c.2861G>T p.G954V | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV99606989; called by muse, mutect2
- RREB1 | c.4559G>A p.R1520Q | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1485517837, COSV100619268; called by muse, mutect2
- RXFP1 | c.1880C>G p.A627G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100313668; called by muse, mutect2
- RXFP2 | c.685T>A p.F229I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100034198; called by muse, mutect2
- SALL4 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs765004478, COSV99409387; called by muse, mutect2, varscan2
- SCN11A | c.1481T>A p.L494H | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV100181275; called by muse, mutect2, varscan2
- SDK1 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV101268541, COSV101269136; called by muse, mutect2, varscan2
- SIGLEC8 | c.1057T>A p.S353T | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV100367217; called by muse, mutect2, varscan2
- SLC12A6 | c.75T>G p.I25M | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100825316; called by muse, mutect2, varscan2
- SLC17A6 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs377657098; called by muse, mutect2, varscan2
- SLC32A1 | c.716C>G p.S239W | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1254196187, COSV54146575, COSV99462048; called by muse, mutect2, varscan2
- SLC7A13 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV99878744; called by muse, mutect2
- SLC9A3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.192); catalogued as rs761872430, COSV99375863; called by muse, mutect2
- SLC9A3 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); catalogued as rs772434234, COSV99375866; called by mutect2, varscan2
- SPAG5 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100410528; called by muse, mutect2
- SPEG | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 67/372 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100403249, COSV100404057, COSV56676473; called by muse, mutect2, varscan2
- SPTY2D1 | c.1357G>T p.V453F | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100311594; called by muse, mutect2
- TAF1 | c.1915G>A p.G639S (on ENST00000373790 / NM_138923.4; = p.G660S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112126, COSV99335313; called by muse, mutect2, varscan2
- TENM3 | c.7954G>A p.E2652K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs1311635891; called by muse, mutect2
- TERF1 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 9/137 reads (7%) | catalogued as COSV99401086; called by muse, mutect2
- TLR4 | c.1158T>G p.S386R (on ENST00000355622 / NM_138554.5; = p.S346R on NM_003266.4) | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100842723; called by muse, mutect2
- TOGARAM1 | c.1850A>G p.N617S | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV100753055; called by muse, mutect2
- TSHZ2 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100295793; called by muse, mutect2, varscan2
- TTC8 | c.912T>A p.F304L (on ENST00000338104 / NM_001288781.1; = p.F288L on NM_144596.4) | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1326439602, COSV100581234; called by muse, mutect2
- TUBGCP2 | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99427512; called by muse, mutect2, varscan2
- UNC13C | c.1088T>A p.I363K | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV99514856; called by muse, mutect2
- UNC5C | c.1993A>G p.S665G | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746202995, COSV101497850; called by muse, mutect2, varscan2
- USH2A | c.7882C>A p.P2628T | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV100232583, COSV56460347; called by muse, varscan2
- WEE2 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101187658; called by muse, mutect2, varscan2
- WNK1 | c.4331G>A p.S1444N (on ENST00000315939 / NM_018979.4; = p.S1197N on NM_014823.3) | Missense Mutation (SNP) | VAF 65/520 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100266944, COSV99049288; called by muse, mutect2, varscan2
- ZNF160 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 51/317 reads (16%) | catalogued as COSV100762294, COSV61999137; called by muse, mutect2, varscan2
- ZNF331 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | catalogued as COSV99467133; called by muse, mutect2, varscan2
- ZNF33A | c.1841G>T p.G614V (on ENST00000458705 / NM_006974.3; = p.G615V on NM_006954.2) | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100275656, COSV56726705; called by muse, mutect2
- ZNF616 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as rs1397373181, COSV100348257; called by muse, mutect2, varscan2
- ZNF676 | c.1439C>A p.P480H (on ENST00000650058; = p.P448H on NM_001001411.3) | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV101236169, COSV68093203, COSV68094043; called by muse, mutect2
- ZNF69 | c.337A>T p.N113Y (on ENST00000429654 / NM_001364730.1; = p.N99Y on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100420971; called by muse, mutect2, varscan2
- ZNF704 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.046); catalogued as COSV100589445; called by muse, mutect2, varscan2
- ZNF804B | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1041546416, COSV60819210, COSV60822900; called by muse, mutect2
- ZNF98 | c.1470C>A p.Y490* | Nonsense Mutation (SNP) | VAF 20/278 reads (7%) | catalogued as COSV100757393; called by muse, mutect2
- ARHGAP21 | c.4448C>T p.P1483L | Missense Mutation (SNP) | VAF 16/558 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- BID | c.427_463del p.M143Wfs*67 (on ENST00000317361 / NM_197966.2; = p.M97Wfs*67 on NM_001196.4) | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel
- CARM1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYFIP1 | c.916C>G p.P306A | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2
- CYP11B2 | c.732del p.S245Lfs*51 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- FAM83A | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-16 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 25/355 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- IGKV3D-20 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2
- IZUMO2 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCTD1 | c.20_33del p.T7Ifs*24 | Frame Shift Del (DEL) | VAF 32/324 reads (10%) | called by mutect2, pindel
- MCEMP1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.545); called by muse, mutect2
- OR11H1 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- OR5B2 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RASGRF2 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- SLC6A3 | c.469_471del p.N157del | In Frame Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- TRAV2 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TRGV4 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZKSCAN5 | c.676dup p.S226Ffs*19 | Frame Shift Ins (INS) | VAF 39/299 reads (13%) | called by mutect2, pindel, varscan2
- ZNF426 | c.513del p.N172Tfs*37 | Frame Shift Del (DEL) | VAF 25/215 reads (12%) | called by mutect2, varscan2
- ZNF454 | c.1547_1548del p.R516Tfs*9 | Frame Shift Del (DEL) | VAF 47/262 reads (18%) | called by pindel, varscan2
- AFF3 | c.420G>A p.Q140= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- AFF4 | c.2928C>T p.L976= | Silent (SNP) | VAF 21/336 reads (6%) | catalogued as COSV99534793; called by muse, mutect2
- ANKS1B | c.1506A>C p.P502= | Silent (SNP) | VAF 26/237 reads (11%) | catalogued as COSV101612659; called by muse, mutect2, varscan2
- CA8 | c.777G>T p.G259= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV100526810; called by muse, mutect2, varscan2
- CADPS | c.2664A>G p.L888= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs1450837404, COSV99337216; called by muse, mutect2, varscan2
- CARMIL1 | c.1038G>A p.G346= | Silent (SNP) | VAF 62/300 reads (21%) | catalogued as COSV100277431; called by muse, mutect2, varscan2
- CCDC15 | c.2613C>T p.I871= | Silent (SNP) | VAF 12/268 reads (4%) | catalogued as rs867042833; called by muse, mutect2
- CFTR | c.4230C>T p.C1410= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV99135133; called by muse, mutect2, varscan2
- CPS1 | c.450G>T p.G150= | Silent (SNP) | VAF 42/327 reads (13%) | catalogued as rs771266355, COSV51818919; called by muse, mutect2, varscan2
- EGFLAM | c.385C>A p.R129= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as COSV100470671, COSV59310046; called by muse, mutect2, varscan2
- EMILIN2 | c.468G>A p.K156= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- EPPIN | c.318C>G p.V106= | Silent (SNP) | VAF 65/312 reads (21%) | catalogued as COSV60549356; called by muse, mutect2, varscan2
- ERBB2 | c.498G>A p.T166= | Silent (SNP) | VAF 37/210 reads (18%) | catalogued as rs370810322, COSV54072416; called by muse, mutect2, varscan2
- FAM135B | c.4080T>C p.T1360= | Silent (SNP) | VAF 101/696 reads (15%) | catalogued as COSV52752698, COSV99421935; called by muse, mutect2, varscan2
- FBXW2 | c.789A>T p.T263= | Silent (SNP) | VAF 66/329 reads (20%) | catalogued as COSV100535165; called by muse, mutect2, varscan2
- FEZF1 | c.1389G>T p.P463= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100484467; called by muse, mutect2, varscan2
- FOXC2 | c.210G>C p.L70= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as COSV100234199; called by muse, mutect2, varscan2
- GAS2 | c.714C>A p.L238= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV53410817, COSV99534923; called by muse, mutect2
- HIF3A | c.288C>T p.F96= (on ENST00000377670 / NM_152795.4; = p.F94= on NM_152794.4) | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as rs978990767, COSV99355680; called by muse, mutect2, varscan2
- HS3ST2 | c.774G>A p.E258= | Silent (SNP) | VAF 46/359 reads (13%) | catalogued as COSV99757874; called by muse, mutect2, varscan2
- HUWE1 | c.3993A>C p.T1331= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99471550; called by mutect2, varscan2
- IRS2 | c.576C>T p.A192= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV101018962; called by muse, mutect2, varscan2
- KCNJ3 | c.39G>A p.Q13= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as COSV99715544, COSV99715651; called by muse, mutect2, varscan2
- KIAA1210 | c.1803A>G p.Q601= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs1419825546; called by muse, mutect2, varscan2
- KLF7 | c.189C>T p.H63= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs750908120, COSV58744739; called by muse, mutect2, varscan2
- KLK5 | c.492T>C p.R164= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV100306975; called by muse, mutect2, varscan2
- MYB | c.1922G>A p.*641= | Silent (SNP) | VAF 34/202 reads (17%) | catalogued as COSV100214726; called by muse, mutect2, varscan2
- NHP2 | c.111C>A p.P37= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV99200924; called by muse, mutect2, varscan2
- OR52M1 | c.609G>T p.L203= | Silent (SNP) | VAF 60/392 reads (15%) | catalogued as COSV100798574; called by muse, mutect2, varscan2
- PABPC5 | c.759A>G p.Q253= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV100442256; called by muse, mutect2, varscan2
- PCDH15 | c.1026T>C p.P342= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV100218544, COSV57260140; called by muse, mutect2
- PCDHB8 | c.1734C>A p.P578= | Silent (SNP) | VAF 26/623 reads (4%) | called by muse, mutect2
- PLEKHG4B | c.963T>C p.F321= (on ENST00000283426; = p.F677= on NM_052909.5) | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as COSV99360093; called by muse, mutect2, varscan2
- PROX1 | c.237G>A p.S79= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as COSV99799059; called by muse, mutect2, varscan2
- PRSS58 | c.552G>T p.V184= | Silent (SNP) | VAF 47/376 reads (13%) | catalogued as COSV101616113; called by muse, mutect2, varscan2
- PTBP1 | c.900C>A p.S300= (on ENST00000349038 / NM_031991.4; = p.S326= on NM_002819.5) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs908899798, COSV100608524; called by muse, mutect2, varscan2
- PTPRB | c.4980T>G p.R1660= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs372617123; called by muse, mutect2, varscan2
- PURG | c.442A>C p.R148= | Silent (SNP) | VAF 41/276 reads (15%) | catalogued as COSV53299271, COSV99988722; called by muse, mutect2, varscan2
- RP1 | c.2862G>T p.G954= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV55116971, COSV99606992; called by muse, mutect2
- SGCZ | c.855C>T p.V285= | Silent (SNP) | VAF 22/199 reads (11%) | catalogued as COSV101168211; called by muse, mutect2, varscan2
- SLC7A5 | c.648C>T p.F216= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs745656437, COSV55363994; called by mutect2, varscan2
- SYNE1 | c.26025T>C p.A8675= (on ENST00000367255 / NM_182961.4; = p.A8627= on NM_033071.3) | Silent (SNP) | VAF 19/284 reads (7%) | catalogued as COSV99559332; called by muse, mutect2
- TAL1 | c.858C>A p.S286= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99595975; called by muse, mutect2, varscan2
- TENM3 | c.4203A>T p.T1401= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101305010; called by muse, mutect2
- THBS1 | c.303G>T p.R101= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV52950370, COSV99527796; called by muse, mutect2, varscan2
- TMEM74 | c.465G>A p.L155= | Silent (SNP) | VAF 13/244 reads (5%) | catalogued as COSV52463809, COSV52464430; called by muse, mutect2
- TNFRSF8 | c.1473C>T p.A491= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs370010968; called by muse, mutect2, varscan2
- TRIM25 | c.561T>G p.S187= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100380962; called by muse, mutect2
- TRIOBP | c.6840C>T p.C2280= (on ENST00000644935 / NM_001039141.3; = p.C567= on NM_007032.5) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs764022321, COSV100730776, COSV60376714; called by mutect2, varscan2
- TRPC6 | c.1353C>T p.T451= | Silent (SNP) | VAF 9/158 reads (6%) | catalogued as COSV100723548; called by muse, mutect2
- TUBGCP2 | c.27C>T p.D9= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs373888351; called by muse, mutect2, varscan2
- USP38 | c.2568G>C p.G856= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100189177; called by muse, mutect2
- ZNF583 | c.1416A>G p.T472= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as COSV99382051; called by muse, mutect2
- ZSWIM8 | c.5085C>T p.P1695= (on ENST00000605216 / NM_001242487.2; = p.P1700= on NM_015037.3) | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs1386852717, COSV55212621, COSV55215390; called by muse, mutect2, varscan2
- AL590867.2 | n.369C>A | RNA (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- IL36B | c.261+1027T>G | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99382619; called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604991 G>T | 5'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- NXF5 | n.713A>G | RNA (SNP) | VAF 51/323 reads (16%) | catalogued as COSV99534258; called by muse, varscan2
- NXF5 | n.712C>A | RNA (SNP) | VAF 50/320 reads (16%) | catalogued as COSV99534260; called by muse, varscan2
- PTHLH | c.-22-200_-22-193del | Intron (DEL) | VAF 50/168 reads (30%) | called by mutect2, varscan2
- SERPINA13P | n.813C>G | RNA (SNP) | VAF 31/222 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.9756G>T | RNA (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100947229; called by muse, mutect2, varscan2
- TTN | c.10361-4909C>A | Intron (SNP) | VAF 60/294 reads (20%) | catalogued as rs1481005451, COSV100604334; called by muse, mutect2, varscan2
